Gene-level copy-number profile of tumor specimen MP2PRT-PAPCNZ-TMP1-A from MP2PRT case MP2PRT-PAPCNZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,207 days).
Specimen MP2PRT-PAPCNZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e2f987cb-0f66-4608-ba85-734c63d98dc4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPCNZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/0cab6dc0-330c-4e3f-af6f-fe657f802723

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 205; copy number 1: 3,141; copy number 2: 55,531; copy number 3: 7.

Homozygous deletions (total copy number 0; autosomes only): 205 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,825,207, 2 genes (within-gene range 0–2): MALLP2, MIR4436A.
- chr2:89,192,500–89,192,752, 1 gene (within-gene range 0–1): IGKV3-25.
- chr2:89,244,781–89,295,455, 7 genes (within-gene range 0–1): IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr2:89,968,867–90,047,057, 9 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19.
- chr2:90,114,838–90,221,384, 9 genes: IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr7:38,239,580–38,340,998, 15 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV6.
- chr9:12,134–13,783, 1 gene: DDX11L5.
- chr9:21,638,285–23,898,054, 30 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2.
- chr9:64,488,600–64,498,745, 2 genes: GXYLT1P6, AL773524.1.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,680,603–106,771,020, 11 genes: IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 285. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
